Somatic mutation profile of tumor specimen TCGA-X4-A8KQ-01A (aliquot TCGA-X4-A8KQ-01A-12D-A364-08) from TCGA case TCGA-X4-A8KQ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.7 years (23,999 days).
Specimen TCGA-X4-A8KQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a69884e9-7128-4553-9604-e73f1f6ea87b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X4-A8KQ-10A (Blood Derived Normal), aliquot TCGA-X4-A8KQ-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5123853b-d32c-4921-b907-ebd8c2286490

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 26, Silent 9, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV59320079; called by muse, mutect2
- ADAMTSL4 | c.1711T>C p.S571P | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.697); catalogued as COSV99647816; called by muse, mutect2, varscan2
- ADGRB3 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53256345; called by muse, mutect2, varscan2
- ASPM | c.9373C>T p.Q3125* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as COSV99660976; called by muse, mutect2, varscan2
- CAMTA1 | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100352148; called by muse, mutect2, varscan2
- CAPZA1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1457638669, COSV99583422; called by muse, mutect2, varscan2
- CAV1 | c.196-1G>T p.X66_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as rs764896355, COSV100592008; called by muse, varscan2
- CCZ1 | c.583T>G p.F195V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100382942; called by muse, mutect2, varscan2
- CSMD2 | c.9689G>A p.R3230H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343666692, COSV99594435; called by muse, mutect2, varscan2
- CYP4F2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.104); catalogued as rs61755872; called by muse, mutect2, varscan2
- DDX1 | c.2045A>G p.D682G | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV99246869; called by muse, mutect2, varscan2
- HMCN1 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs144772706; called by muse, mutect2, varscan2
- HSPA2 | c.1664C>T p.T555M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.152); catalogued as rs1389909173, COSV55971339; called by muse, mutect2, varscan2
- IFNA17 | c.125C>G p.A42G | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs141448576; called by muse, mutect2, varscan2
- ITGA4 | c.2581T>C p.C861R | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101223645; called by muse, mutect2, varscan2
- LRIG2 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV100743644; called by muse, mutect2, varscan2
- MYO9B | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1488588943, COSV101261829; called by muse, mutect2, varscan2
- NANOG | c.512C>A p.A171E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs1418923513, COSV99981713; called by muse, mutect2, varscan2
- NEB | c.4096T>C p.S1366P | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99427056; called by muse, mutect2, varscan2
- NYAP2 | c.1490C>A p.A497E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as COSV99798189; called by muse, mutect2, varscan2
- OR10Q1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs746612596, COSV100372159, COSV57471918; called by muse, mutect2, varscan2
- OR9I1 | c.735C>G p.I245M | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.548); catalogued as COSV100110424; called by muse, mutect2
- POSTN | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs201568682, COSV65713360; called by muse, mutect2
- RNF43 | c.647C>A p.S216* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV68456847, COSV68457801; called by mutect2, varscan2
- ROBO4 | c.968T>C p.V323A | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100127814; called by muse, mutect2, varscan2
- SLC6A6 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV62647906; called by muse, mutect2, varscan2
- SPATS2 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100423666; called by muse, mutect2, varscan2
- TNFRSF8 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs777410629, COSV99821862; called by muse, mutect2, varscan2
- TRIM56 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.541); catalogued as COSV100047692; called by muse, mutect2, varscan2
- HEATR9 | c.249G>A p.W83* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- KMT2D | c.2490_2491del p.E830Dfs*8 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | called by mutect2, pindel, varscan2
- NCOR2 | c.447dup p.P150Sfs*8 | Frame Shift Ins (INS) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- SAMD9 | c.2451del p.I818* | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | called by mutect2, pindel, varscan2
- TP53 | c.944_964delinsT p.S315Ffs*15 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by muse*, pindel
- FASN | c.5406G>A p.E1802= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs776117487, COSV100148255; called by muse, mutect2, varscan2
- GALNT6 | c.1149C>T p.N383= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs138065864; called by muse, mutect2, varscan2
- GRIN2A | c.231C>T p.T77= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as COSV58032505; called by muse, mutect2, varscan2
- IRX1 | c.360C>T p.Y120= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV57358565; called by muse, mutect2, varscan2
- MED23 | c.3972T>A p.A1324= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99256246; called by muse, mutect2, varscan2
- PCDHB5 | c.1131C>T p.N377= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV50647244; called by muse, mutect2, varscan2
- PHAX | c.84G>A p.P28= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1358144666, COSV99881653; called by muse, mutect2, varscan2
- PTPN23 | c.1548C>T p.H516= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs151244361; called by muse, mutect2, varscan2
- SEMA5A | c.1674C>T p.S558= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as rs141153482; called by muse, mutect2
